TARGET case TARGET-10-PALKMM — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/3e1a2110-4348-456f-b56d-6bcb7c5dfcd0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 1,037 days (2.8 years).

Diagnoses (1)
1. Precursor B-cell lymphoblastic leukemia: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Age at diagnosis: 12.6 years (4,585 days); Year of diagnosis: 2002; Days to last follow up: 1,037 days (2.8 years).

Biospecimens (2 samples)
- Sample TARGET-10-PALKMM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PALKMM-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_I_20230727.xlsx:
- First Event: Relapse
- Event Free Survival Time in Days: 515
- Overall Survival Time in Days: 1037
- Protocol: P9906
- WBC at Diagnosis: 12
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 2.48
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.00178617
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.1
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 39
- BMA Blasts Day 29: 0
- Karyotype: 45,XY,DEL(1)(Q42),INV(1)(P13Q32),ADD(2)(P25),DER(4)DEL(4)(P15)ADD(4)(Q31),DER(6)T(6;14)(P21;Q32),DEL(6)(Q26),DIC(8;9)(P11.2;P13),ADD(9)(P11),DER(14)T(6;14)(P21;Q32),ADD(17)(P13)[6]/46,XY[11]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B precursor (Non-T, Non-B ALL)
- ALL Molecular Subtype: None of above
